Gene-level copy-number profile of tumor specimen TCGA-N8-A4PM-01A from TCGA case TCGA-N8-A4PM, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IB; Age at diagnosis: 73.8 years (26,971 days).
Specimen TCGA-N8-A4PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.c42a82ed-5d86-4635-abf2-05933812e290.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 827 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f15aaf41-77b6-4077-b79b-e5269991fbef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3; copy number 2: 5,574; copy number 3: 15,699; copy number 4: 35,506; copy number 5: 1,427; copy number 6: 1,283; copy number 7: 182; copy number 8: 80; copy number 11: 12; copy number 14: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PM-01A-11D-A28Q-01): tumor purity 0.9, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 36 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:19,615,789–20,483,991, 36 genes, copy number 11–14: SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1, AKAP10, AC005730.3, AC005730.2, SPECC1, AC005730.1, KCTD9P1, RNU6-258P, AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
